Somatic mutation profile of tumor specimen TCGA-2G-AAG7-01A (aliquot TCGA-2G-AAG7-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAG7, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 33.3 years (12,180 days).
Specimen TCGA-2G-AAG7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3a9ba81-cca7-4797-a893-72494f75e105.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAG7-10A (Blood Derived Normal), aliquot TCGA-2G-AAG7-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f4b7c02-101d-4901-87ef-fd25e182a8ee

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, Nonsense Mutation 2, 5'UTR 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.40del p.L14Sfs*58 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | catalogued as COSV56232785; called by mutect2, pindel, varscan2
- BPTF | c.2833G>T p.E945* | Nonsense Mutation (SNP) | VAF 23/80 reads (29%) | catalogued as COSV58835826; called by muse, mutect2, varscan2
- COG8 | c.1093G>T p.G365C | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54742291; called by muse, mutect2, varscan2
- FAM71E2 | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs752437843; called by muse, mutect2, varscan2
- FLT3LG | c.178G>C p.V60L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.141); catalogued as rs367551792, COSV52618285; called by muse, mutect2, varscan2
- PCDHB9 | c.1665C>G p.N555K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs782636682; called by muse, mutect2, varscan2
- PCDHGA9 | c.2411C>A p.T804N | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.065); catalogued as rs765508317; called by muse, mutect2, varscan2
- CCT6A | c.113T>A p.L38Q | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCTN1 | c.2895G>C p.E965D | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- DLG2 | c.2264A>G p.Y755C | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSR | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- H4C2 | c.178A>G p.K60E | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- RYR1 | c.13472C>T p.P4491L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPEN | c.1983G>A p.W661* | Nonsense Mutation (SNP) | VAF 34/118 reads (29%) | called by muse, mutect2, varscan2
- TCHHL1 | c.2479G>C p.A827P | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); called by muse, mutect2
- ZBTB49 | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.026); called by muse, mutect2
- ZNF30 | c.413A>G p.H138R | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEBPA | c.777G>T p.A259= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as rs967066471; called by mutect2, varscan2
- TCERG1L | c.615G>A p.P205= | Silent (SNP) | VAF 45/106 reads (42%) | catalogued as rs773472885, COSV64051481; called by muse, mutect2, varscan2
- ZNF823 | c.579A>G p.K193= (on ENST00000341191 / NM_001297610.2; = p.K149= on NM_017507.2) | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as COSV57875984; called by muse, mutect2, varscan2
- PEX1 | c.-1G>C | 5'UTR (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- SNX31 | c.-9C>A | 5'UTR (SNP) | VAF 45/203 reads (22%) | catalogued as rs758142649; called by muse, mutect2, varscan2
